Surgical pathology report (de-identified scan), TCGA case TCGA-BD-A2L6, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BD-A2L6-01A (Primary Tumor).

[page 1 of 3]
ADDENDA:

Addendum

Grocott stain for fungi and acid fast stain for Mycobacteria are negative on section 3A.

FINAL DIAGNOSIS:

PART 1: GALLBLADDER, CHOLECYSTECTOMY

CHRONIC CHOLECYSTITIS AND CHOLESTEROSIS WITH REACTIVE LYMPH NODE.

PART 2: LIVER, LEFT LOBE MASS, LEFT LOBECTOMY

A. MODERATELY DIFFERENTIATED HEPATOCELLULAR CARCINOMA (13 CM) WITH FOCAL CLEAR CELL CHANGE AND GIANT CELL TRANSFORMATION.

B. MICROVASCULAR INVASION SEEN.

C. ALL SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.

D. PATHOLOGIC STAGING: pT2 Nx Mx.

E. GRANULOMATOUS HEPATITIS WITH NUMEROUS PORTAL AND LOBULAR EPITHELIOID GRANULOMAS CUFFED BY LYMPHOCYTES.

F. PERITUMORAL PORTAL TO PORTAL BRIDGING FIBROSIS

PART 3: LIVER, RIGHT LOBE, SEGMENT 6, WEDGE EXCISION

A. SUBCAPSULAR SCLEROSIS HEMANGIOMA.

B. GRANULOMATOUS HEPATITIS WITH NUMEROUS PORTAL AND LOBULAR EPITHELIOID GRANULOMAS CUFFED BY LYMPHOCYTES.

C. SUBCAPSULAR HEMORRHAGE, HEAT ARTIFACT, AND PORTAL TO PORTAL BRIDGING FIBROSIS. AGE = 3/6.

D. MINIMAL MACROVESICULAR STEATOSIS.

Comment:
The granulomatous reaction is quite prominent and is being further evaluated by grocott and APB stains. Sarcoidosis, a drug reaction, male primary biliary cirrhosis, and autoimmune hepatitis are also in the differential diagnosis.

Finally, it should be kept in mind that tumors can excite a granulomatous type iv hypersensitivity response. Clinical correlation is needed.

GROSS DESCRIPTION:

The specimen is received in 3 parts.

Part 1 is received fresh labeled with the patient's name, initials and "gallbladder". Received is a dusky pink, smooth, gallbladder (8 x 3 x 1.8 cm) filled with amber, viscid bile. No gallstones are present. The gallbladder open circumference measures 5.6 cm and has a wall thickness of 0.1 cm. The mucosa is bile stained, velvety and smooth with scattered yellow speckling. The cystic duct is patent. No lymph node is identified. The specimen is representatively submitted.

Ink code:

Blue - cystic duct resection margin

Section code:

1A - Representative section of shaved cystic duct resection margin, neck, body, and fundus.

Part 2 is received fresh labeled with the patient's name, initials and "left lobe of liver". It received is a left lobectomy liver resection, 14 x 12 x 7.5 cm, 611 g. The capsule is intact smooth with a subcapsular enlarged ivory hemorrhagic oval 13 x 9.5 x 7.5 cm, tumor mass. A portion of tumor and normal liver with resection margin has been previously banked, for research, prior to receipt of specimen. The tumor extends to within 1.4 cm of the liver parenchymal and vascular resection margins. The cut surface of the liver mass is soft, nodular, ivory-white and with punctate hemorrhage. The uninvolved liver parenchyma appears unremarkable. Digital images are taken. The specimen is representatively submitted.

Additional studies:

Tissue is banked.

Digital images are taken.

Ink code:

Green - liver parenchymal resection margin.

Section code:

2A - 2B - vascular and parenchymal resection margins

2C - 2G - representative sections tumor relationship to capsule and hemorrhage

2H - tumor/transition to normal liver parenchymal resection margin

Part 3 is received fresh labeled with the patient's name, initials and "right lobe segment 6". Received is a single, unorientated, shallow 2.4 x 1.8 x 1 cm, liver lesion excision. Centrally located is a light red, well circumscribed, 1.2 x 1 cm lesion that extends to within 0.1 cm of the nearest resection margin-deep. A gross consultation is performed with an intraoperative diagnosis completed. The specimen is serially sectioned and entirely submitted in cassettes labeled 3A-3C.

INTRAOPERATIVE CONSULTATION:

2AGR: LIVER, LEFT LOBECTOMY (gross consultation)-
A. MALIGNANT, PROBABLY HCC

B. MARGINS GROSSLY FREE OF TUMOR-TRUE MARGIN INKED GREEN

C. TISSUE TAKEN FOR RESEARCH, TISSUE BANK

3AGR: LIVER, RIGHT LOBE, SEGMENT 6, WEDGE BIOPSY (gross consultation)-

1CD-0-3

carcinoma, hepatocellular, NOS

8170/3

Site: liver C22.0

8/18/11

Case is (cirr):		

[page 2 of 3]
MARGIN GROSSLY FREE OF LESION (

MICROSCOPIC:

Part 1: Histologic section demonstrates a gallbladder with thickened wall and focal mild chronic inflammation. Foamy macrophages in lamina propria and epithelium are also identified.

Part 2: Histologic sections demonstrate a moderately differentiated hepatocellular carcinoma with tumor cells arranged in cords and trabeculae. Clear cell pattern and occasional giant tumor cells are identified. Extensive hemorrhage and focal myxoid changes are also present. The background liver shows granulomas and a distorted architecture with portal to portal bridging fibrosis. The fibrous tissue septae contain moderate lymphocytic infiltrate with ductular proliferation. Prominent portal fibrosis and portal inflammation with focal lymphoid aggregates are present. The interlobular bile ducts are intact showing no florid duct lesion or significant ductal fibrosis. No portal or periportal granulomas are seen. The lobule shows granulomas with scattered chronic inflammation and occasional acidophilic hepatocytes. No confluent necrosis is seen. Mild lymphocytosis is seen within the sinusoidal space. No significant steatosis is appreciated. No significant cholestasis is seen. No ground glass cells, hepatocyte globules, Mallory's hyaline or other prominent pigment depositions are seen.

Part 3: The liver parenchyma is similar peritumoral tissue in part 2 and shows a sclerosed hemangioma.

The following statement applies to all immunohistochemistry, In situ Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by the '88 regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of 2 to a maximum of 84 hours. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY LIVER HEPATOCELLULAR CARCINOMA TUMORS

SPECIMEN TYPE: Total left lobectomy

FOCALITY: Solitary: LEFT LOBE

TUMOR SIZE: Greatest dimension: 13 cm
Additional dimensions: 9.5 X 7.5 cm

HISTOLOGIC TYPE: Hepatocellular carcinoma

HISTOLOGIC GRADE: GII: Moderately differentiated

MACROSCOPIC VENOUS (LARGE VESSEL) INVASION (V):
Not identified

MICROSCOPIC (SMALL VESSEL) INVASION (L):
Present

LIVER-PERINEURAL INVASION: Not identified

PATHOLOGIC STAGING (pTNM): pT2
pNX
Number of regional lymph nodes examined: 0
pM0

MARGINS: Parenchymal Margin uninvolved by invasive carcinoma

ADDITIONAL PATHOLOGIC FINDINGS: No fibrosis to moderate fibrosis (Ishak 0-4)
Hepatitis Type: granulomatous

[page 3 of 3]
PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Liver resection in obese and diabetic male; no liver function tests available in Power Chart.

PROCEDURE: Not answered.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Gallbladder

Taken:

Stain/cnt Block

H&E x 1 A

Received:

Part 2: Left Lobe Liver

Taken:

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

H&E x 1 H

Received:

Part 3: Right Lobe Liver

Taken

Stain/cnt Block

AcidFast x 1 A

Grocott x 1 A

H&E x 1 A

H&E x 1 B

H&E x 1 C

Received:

TC1

Source: NCI Genomic Data Commons file 5a280d6f-e7d8-470c-8d15-04b33e1e6eba (TCGA-BD-A2L6.6E795E68-4CFC-4DC9-A072-9A78C59CE10A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).